FM case AD15359 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/38b73e5d-4799-4ba3-bee5-344e060d2c47

Male, 59.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 73% (pathologist estimate recorded by GDC). Sample type: Metastatic.
